Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KN-01A (Primary Tumor).

ILIPAA Discrepancy		☒
Dup-/Synchronous Primary Tumor		☒

Sample Type TUMOUR

Sample Preparation

Site of Primary (Event)

Site of Tissue

Year of Sample Collection

Age at Sample Collection (yrs)

Sample Comments

Days to Procedure Date

Days to Diagnosis

Type of Procedure

Site of Primary (Histology)

Bilateral Disease

Tumour Size (cm)

Histology

Grade/Differentiation

Pathological T

Pathological N

Number of Nodes Sampled

Number of Nodes Positive

Clinical M

Histology Comments

Fresh Frozen

Uterine

Uterus

1CD-0-3

adenocarcinoma, endometrioid, NOS

8380/3

Site: Endometrium C54.1

lw 8/23/11

0

14

Surgical resection

Endometrium

N/A

6

Endometrioid adenocarcinoma, NOS

III

T1c

N0

0

20

M0

Source: NCI Genomic Data Commons file bba70c94-dc57-4584-ac15-db8df2220210 (TCGA-DF-A2KN.A61CE064-B18B-429E-93F1-BA0FC06AB310.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).